CCDI case PBCSYX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/c2df47b6-b193-4ffc-aa6e-fc575ad5181f

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 12.2 years (4,458 days).

Biospecimens (3 samples)
- Sample 0DYNML: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DYNN4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DYNNY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
